Somatic mutation profile of tumor specimen TCGA-VQ-A8DL-01A (aliquot TCGA-VQ-A8DL-01A-11D-A364-08) from TCGA case TCGA-VQ-A8DL, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 69.3 years (25,299 days).
Specimen TCGA-VQ-A8DL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 15dedd34-208e-4a20-96b0-b73c7cb23ae1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VQ-A8DL-10A (Blood Derived Normal), aliquot TCGA-VQ-A8DL-10A-01D-A362-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f01e50e4-8685-41ed-bd09-7eb8cb802539

The open-access MAF lists 172 somatic variants for this specimen: 151 protein-altering or splice-affecting, 16 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Frame Shift Ins 42, Missense Mutation 37, Frame Shift Del 31, Silent 16, In Frame Ins 12, In Frame Del 10, Splice Site 9, Nonsense Mutation 6, 5'Flank 3, Translation Start Site 2, Intron 2, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC090517.4 | c.1777A>G p.K593E | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.341); catalogued as rs768976746, COSV50997335, COSV99974631; called by muse, mutect2, varscan2
- AHNAK2 | c.16728G>T p.M5576I | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs369118861; called by muse, mutect2
- AKAP13 | c.1306_1307insCTG p.Q436delinsPE | In Frame Ins (INS) | VAF 11/46 reads (24%) | catalogued as COSV100773965; called by mutect2, pindel, varscan2
- AP3B2 | c.1780G>T p.A594S | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.246); catalogued as COSV55609302, COSV99916604; called by muse, mutect2, varscan2
- ATAD2 | c.4100G>A p.R1367H | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs147449805; called by muse, mutect2, varscan2
- CENPL | c.95A>C p.E32A | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); catalogued as COSV100616373; called by muse, mutect2, varscan2
- CNTN5 | c.1029T>A p.S343R | Missense Mutation (SNP) | VAF 11/152 reads (7%) | SIFT tolerated (0.67); PolyPhen benign (0.345); catalogued as COSV99678027; called by muse, mutect2
- COPA | c.2234G>A p.R745H | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs138441444; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CR2 | c.1487G>A p.G496D | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100889662; called by muse, mutect2, varscan2
- DHCR7 | c.1354G>A p.A452T | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0.097); catalogued as rs140400648, COSV100831972; called by muse, mutect2, varscan2
- DPRX | c.220G>T p.A74S | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.872); catalogued as COSV100934089; called by muse, mutect2, varscan2
- FANCM | c.2543C>T p.T848I | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.168); catalogued as rs889187666, COSV99951159; called by muse, mutect2, varscan2
- FANCM | c.3270A>T p.Q1090H | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.467); catalogued as COSV99951160; called by muse, mutect2, varscan2
- FLG2 | c.2558G>T p.S853I | Missense Mutation (SNP) | VAF 74/349 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as COSV101165941; called by muse, mutect2, varscan2
- GSKIP | c.246A>C p.E82D | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.4); PolyPhen benign (0.006); catalogued as COSV101347621, COSV68451577; called by muse, mutect2, varscan2
- KCNT2 | c.3371T>G p.V1124G | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as COSV99654451; called by muse, mutect2, varscan2
- KRT35 | c.232G>A p.A78T | Missense Mutation (SNP) | VAF 12/192 reads (6%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs1358681334, COSV55842978; called by muse, mutect2
- LYN | c.593G>A p.R198Q | Missense Mutation (SNP) | VAF 52/107 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.775); catalogued as rs1210415750, COSV70205934; called by muse, mutect2, varscan2
- MFSD14A | c.1265A>T p.Q422L | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV99790913; called by muse, mutect2, varscan2
- MORC4 | c.1459C>A p.Q487K | Missense Mutation (SNP) | VAF 37/178 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.039); catalogued as COSV99717304; called by muse, mutect2, varscan2
- MRGPRX1 | c.178G>A p.A60T | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.365); catalogued as rs1305417663, COSV57107474; called by muse, mutect2, varscan2
- MUC7 | c.653C>T p.P218L | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.636); catalogued as COSV100512328, COSV59217754; called by muse, varscan2
- NCSTN | c.1718A>G p.N573S | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.795); catalogued as rs778530437, COSV99667258; called by muse, mutect2, varscan2
- NECTIN2 | c.1024C>A p.Q342K | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.61); PolyPhen benign (0.18); catalogued as COSV99375066; called by muse, mutect2, varscan2
- OR9A4 | c.584C>T p.T195M | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.067); catalogued as rs369571264; called by muse, mutect2, varscan2
- PCDH17 | c.1795C>T p.R599C | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1174454338, COSV64976369, COSV64976851; called by muse, mutect2, varscan2
- PCDHGA5 | c.1676C>T p.T559M | Missense Mutation (SNP) | VAF 38/171 reads (22%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.046); catalogued as rs760966863, COSV54003473; called by muse, mutect2, varscan2
- PCM1 | c.271C>T p.Q91* | Nonsense Mutation (SNP) | VAF 5/19 reads (26%) | catalogued as rs1304808259, COSV100279196; called by muse, mutect2, varscan2
- PITPNM1 | c.1828dup p.L610Pfs*31 | Frame Shift Ins (INS) | VAF 20/80 reads (25%) | catalogued as rs1308308846; called by mutect2, pindel, varscan2
- PTEN | c.930_931insC p.N311Qfs*2 | Frame Shift Ins (INS) | VAF 32/112 reads (29%) | catalogued as COSV100910401; called by mutect2, pindel, varscan2
- RFXANK | c.484_485insAGC p.S162delins* | Nonsense Mutation (INS) | VAF 12/45 reads (27%) | catalogued as COSV100284539; called by mutect2, pindel, varscan2
- RNF20 | c.1222C>G p.L408V | Missense Mutation (SNP) | VAF 18/116 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.162); catalogued as COSV101206542; called by muse, mutect2, varscan2
- RPRD2 | c.4348T>G p.F1450V | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV100955117; called by muse, mutect2, varscan2
- SYNPO2 | c.2014G>T p.E672* | Nonsense Mutation (SNP) | VAF 11/36 reads (31%) | catalogued as rs1157302254, COSV100205776, COSV61115463; called by muse, mutect2, varscan2
- TIE1 | c.2536G>A p.G846R | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1289117410; called by muse, mutect2, varscan2
- TOGARAM1 | c.3476C>T p.S1159L | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV100818086; called by muse, mutect2, varscan2
- TOP2A | c.2229G>T p.K743N | Missense Mutation (SNP) | VAF 40/353 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV70732591; called by muse, mutect2, varscan2
- TRIM28 | c.1474_1475insA p.R492Qfs*9 | Frame Shift Ins (INS) | VAF 4/20 reads (20%) | catalogued as COSV99449166; called by mutect2, pindel, varscan2
- TSR2 | c.563G>T p.R188L | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.098); catalogued as COSV100911124; called by mutect2, varscan2
- WDFY1 | c.1228C>T p.H410Y | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); catalogued as COSV99239549; called by muse, mutect2, varscan2
- WFS1 | c.1423C>A p.P475T | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV99901313; called by muse, mutect2, varscan2
- ZNF544 | c.1470A>C p.K490N | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs1318176495, COSV54135196, COSV99516990; called by muse, mutect2, varscan2
- ZNRF3 | c.2509G>C p.D837H (on ENST00000544604 / NM_001206998.2; = p.D737H on NM_032173.3) | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as COSV100238553; called by muse, mutect2
- ACO1 | c.945dup p.S316* | Frame Shift Ins (INS) | VAF 59/216 reads (27%) | called by mutect2, pindel, varscan2
- ADAM28 | c.620_627del p.E207Vfs*5 | Frame Shift Del (DEL) | VAF 36/140 reads (26%) | called by mutect2, pindel, varscan2
- ADARB1 | c.1075_1078+7del p.X359_splice | Splice Site (DEL) | VAF 6/29 reads (21%) | called by mutect2, pindel, varscan2
- ADCK5 | c.289_322del p.I97Sfs*15 | Frame Shift Del (DEL) | VAF 6/37 reads (16%) | called by mutect2, pindel
- ADCY10 | c.1258_1261dup p.Y421Lfs*24 | Frame Shift Ins (INS) | VAF 16/88 reads (18%) | called by mutect2, pindel, varscan2
- AKAP6 | c.1448dup p.R484Kfs*3 | Frame Shift Ins (INS) | VAF 33/168 reads (20%) | called by mutect2, pindel, varscan2
- ALDH18A1 | c.1152+1_1152+3del p.X384_splice | Splice Site (DEL) | VAF 9/57 reads (16%) | called by mutect2, pindel*
- ANO4 | c.2611_2619del p.Y871_Y873del (on ENST00000392977 / NM_001286615.2; = p.Y836_Y838del on NM_178826.4) | In Frame Del (DEL) | VAF 9/69 reads (13%) | called by mutect2, pindel, varscan2
- ARFGEF2 | c.2388_2390dup p.Q796_Y797ins* | Nonsense Mutation (INS) | VAF 23/131 reads (18%) | called by mutect2, pindel, varscan2
- ARHGEF39 | c.447_448insAC p.P150Tfs*16 | Frame Shift Ins (INS) | VAF 15/61 reads (25%) | called by mutect2, pindel, varscan2
- ARID1B | c.4456dup p.M1486Nfs*11 | Frame Shift Ins (INS) | VAF 14/69 reads (20%) | called by mutect2, pindel, varscan2
- ATG16L1 | c.1383_1389del p.C461* (on ENST00000392017 / NM_030803.7; = p.C442* on NM_017974.4) | Frame Shift Del (DEL) | VAF 24/98 reads (24%) | called by mutect2, pindel, varscan2
- ATP8B2 | c.2499_2500insTTG p.L833dup (on ENST00000672630; = p.L800dup on NM_001367934.1 and 3 other RefSeq transcripts) | In Frame Ins (INS) | VAF 28/134 reads (21%) | called by mutect2, pindel, varscan2
- ATP9A | c.306_307del p.T104Lfs*16 | Frame Shift Del (DEL) | VAF 10/60 reads (17%) | called by pindel, varscan2
- BCL11A | c.2336_2348del p.S779Nfs*3 (on ENST00000335712 / NM_001365609.1; = p.S813Nfs*3 on NM_022893.4) | Frame Shift Del (DEL) | VAF 15/94 reads (16%) | called by mutect2, pindel, varscan2
- BOC | c.527_530del p.N176Tfs*2 | Frame Shift Del (DEL) | VAF 30/59 reads (51%) | called by pindel, varscan2
- BRD1 | c.1117_1122del p.G373_G374del | In Frame Del (DEL) | VAF 20/113 reads (18%) | called by mutect2, pindel, varscan2
- C1orf131 | c.449_450del p.K150Tfs*3 | Frame Shift Del (DEL) | VAF 7/39 reads (18%) | called by mutect2, pindel*
- C1orf210 | c.18_19dup p.T7Kfs*30 | Frame Shift Ins (INS) | VAF 9/41 reads (22%) | called by mutect2, pindel, varscan2
- C2CD3 | c.3423_3424insGTT p.T1141_T1142insV | In Frame Ins (INS) | VAF 14/80 reads (18%) | called by mutect2, pindel*, varscan2
- CASZ1 | c.4255_4257dup p.A1419dup | In Frame Ins (INS) | VAF 8/30 reads (27%) | called by mutect2, pindel, varscan2
- CCNI2 | c.494_518del p.Y165Wfs*10 | Frame Shift Del (DEL) | VAF 12/92 reads (13%) | called by mutect2, pindel
- CD47 | c.605_606del p.Y202Ffs*27 | Frame Shift Del (DEL) | VAF 38/128 reads (30%) | called by pindel, varscan2
- CFAP74 | c.4369_4380del p.Q1457_L1460del | In Frame Del (DEL) | VAF 12/67 reads (18%) | called by mutect2, pindel, varscan2
- DBF4 | c.1632dup p.V545Cfs*12 | Frame Shift Ins (INS) | VAF 26/139 reads (19%) | called by mutect2, pindel, varscan2
- DDX19B | c.1114_1115dup p.A373Gfs*4 | Frame Shift Ins (INS) | VAF 10/27 reads (37%) | called by mutect2, pindel, varscan2
- DEPDC1 | c.2_7del p.ME1_?2 | Translation Start Site (DEL) | VAF 14/87 reads (16%) | called by mutect2, pindel, varscan2
- DUOX1 | c.4340_4343dup p.S1449Gfs*12 | Frame Shift Ins (INS) | VAF 20/80 reads (25%) | called by mutect2, pindel, varscan2
- DUSP4 | c.868_869dup p.C291Sfs*6 | Frame Shift Ins (INS) | VAF 12/43 reads (28%) | called by mutect2, pindel, varscan2
- DYRK3 | c.1765dup p.*589Lfs*35 | Frame Shift Ins (INS) | VAF 19/89 reads (21%) | called by mutect2, pindel, varscan2
- EGFL8 | c.321_322del p.L108Hfs*3 | Frame Shift Del (DEL) | VAF 6/28 reads (21%) | called by pindel, varscan2
- EIF2AK3 | c.2044dup p.W682Lfs*7 | Frame Shift Ins (INS) | VAF 14/56 reads (25%) | called by mutect2, pindel, varscan2
- ELL3 | c.979_985del p.R327* | Frame Shift Del (DEL) | VAF 15/65 reads (23%) | called by mutect2, pindel, varscan2
- ENC1 | c.442_445dup p.C149* | Nonsense Mutation (INS) | VAF 25/76 reads (33%) | called by mutect2, pindel, varscan2
- ENPP5 | c.395_398del p.H132Lfs*12 | Frame Shift Del (DEL) | VAF 17/63 reads (27%) | called by mutect2, pindel, varscan2
- ERI1 | c.915_918dup p.V307Sfs*10 | Frame Shift Ins (INS) | VAF 15/65 reads (23%) | called by mutect2, pindel, varscan2
- EXOC3 | c.593_596del p.S198Wfs*58 | Frame Shift Del (DEL) | VAF 13/56 reads (23%) | called by mutect2, pindel, varscan2
- FBXO27 | c.515_516dup p.G173Rfs*38 | Frame Shift Ins (INS) | VAF 17/88 reads (19%) | called by mutect2, pindel, varscan2
- FMO3 | c.382_383del p.T128Hfs*2 | Frame Shift Del (DEL) | VAF 17/80 reads (21%) | called by mutect2, pindel, varscan2
- FTL | c.240_247del p.D81Efs*4 | Frame Shift Del (DEL) | VAF 4/25 reads (16%) | called by mutect2, pindel
- GALK2 | c.504+1_504+5del p.X168_splice | Splice Site (DEL) | VAF 8/40 reads (20%) | called by mutect2, pindel
- GLUL | c.803+1_803+3del p.X268_splice | Splice Site (DEL) | VAF 6/36 reads (17%) | called by mutect2, pindel, varscan2
- GNPTAB | c.51_52del p.Y18Wfs*36 | Frame Shift Del (DEL) | VAF 6/22 reads (27%) | called by mutect2, varscan2
- GZF1 | c.1459+4_1459+7del p.X487_splice | Splice Site (DEL) | VAF 12/41 reads (29%) | called by mutect2, pindel, varscan2
- HAAO | c.631-2_639del p.X211_splice | Splice Site (DEL) | VAF 12/54 reads (22%) | called by mutect2, pindel
- HNRNPL | c.1690_1693dup p.Y565Sfs*69 | Frame Shift Ins (INS) | VAF 6/39 reads (15%) | called by mutect2, pindel, varscan2
- IRF2 | c.640del p.V214Sfs*3 | Frame Shift Del (DEL) | VAF 23/54 reads (43%) | called by mutect2, pindel, varscan2
- JAG2 | c.760_770del p.G254Rfs*18 | Frame Shift Del (DEL) | VAF 17/91 reads (19%) | called by mutect2, pindel, varscan2
- KCNH5 | c.892_894dup p.L298dup | In Frame Ins (INS) | VAF 13/44 reads (30%) | called by mutect2, pindel, varscan2
- KRBA2 | c.239_242dup p.S82Afs*11 | Frame Shift Ins (INS) | VAF 14/48 reads (29%) | called by mutect2, pindel
- LRRK2 | c.210_211insG p.Y71Vfs*38 | Frame Shift Ins (INS) | VAF 16/41 reads (39%) | called by mutect2, pindel*, varscan2
- LXN | c.19_36del p.N7_R12del | In Frame Del (DEL) | VAF 20/82 reads (24%) | called by mutect2, pindel, varscan2
- MAPK6 | c.365dup p.L124Ffs*34 | Frame Shift Ins (INS) | VAF 13/58 reads (22%) | called by mutect2, pindel, varscan2
- MED21 | c.88_90del p.G30del | In Frame Del (DEL) | VAF 23/71 reads (32%) | called by mutect2, pindel, varscan2
- MROH1 | c.1239del p.I414Lfs*18 | Frame Shift Del (DEL) | VAF 4/31 reads (13%) | called by mutect2, pindel
- MRPL37 | c.171dup p.I58Hfs*81 | Frame Shift Ins (INS) | VAF 14/60 reads (23%) | called by mutect2, pindel, varscan2
- MTBP | c.-1_3delinsC | Translation Start Site (DEL) | VAF 12/64 reads (19%) | called by pindel, varscan2*
- MTERF2 | c.987_990dup p.Q331Sfs*31 | Frame Shift Ins (INS) | VAF 45/173 reads (26%) | called by mutect2, pindel, varscan2
- NEDD9 | c.2284_2304del p.T762_T768del | In Frame Del (DEL) | VAF 30/99 reads (30%) | called by mutect2, pindel, varscan2
- PBRM1 | c.3283_3287delinsT p.V1095Sfs*63 (on ENST00000296302 / NM_001366071.2; = p.V1070Sfs*63 on NM_018313.5) | Frame Shift Del (DEL) | VAF 10/51 reads (20%) | called by pindel, varscan2*
- PCDH10 | c.1024_1025insTT p.C342Ffs*5 | Frame Shift Ins (INS) | VAF 15/94 reads (16%) | called by mutect2, pindel, varscan2
- PIFO | c.231_234dup p.V79Sfs*5 | Frame Shift Ins (INS) | VAF 9/59 reads (15%) | called by mutect2, pindel
- PIP4K2A | c.106_107insAGCG p.P36Qfs*17 | Frame Shift Ins (INS) | VAF 3/32 reads (9%) | called by mutect2, pindel
- PKD2L2 | c.1503_1506del p.Y501* | Frame Shift Del (DEL) | VAF 25/127 reads (20%) | called by mutect2, pindel, varscan2
- PLOD1 | c.1561_1581del p.W521_P527del | In Frame Del (DEL) | VAF 4/42 reads (10%) | called by mutect2, pindel
- PPP1R16A | c.849_851dup p.L284dup | In Frame Ins (INS) | VAF 3/28 reads (11%) | called by mutect2, pindel
- PPP3CB | c.1185_1186+4del p.X395_splice | Splice Site (DEL) | VAF 16/76 reads (21%) | called by mutect2, pindel, varscan2
- PRAMEF15 | c.293G>C p.R98T | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- PRMT3 | c.503_515delinsTA p.R168Ifs*2 | Frame Shift Del (DEL) | VAF 22/86 reads (26%) | called by pindel, varscan2*
- PRORP | c.1424+3_1424+6dup | Nonsense Mutation (INS) | VAF 15/85 reads (18%) | called by mutect2, pindel, varscan2
- PSMB3 | c.138_139del p.D47Pfs*12 | Frame Shift Del (DEL) | VAF 7/72 reads (10%) | called by mutect2, pindel, varscan2
- RALGPS2 | c.1224_1225dup p.T409Rfs*19 | Frame Shift Ins (INS) | VAF 18/115 reads (16%) | called by mutect2, pindel, varscan2
- RASSF10 | c.1402dup p.V468Gfs*27 | Frame Shift Ins (INS) | VAF 4/36 reads (11%) | called by mutect2, varscan2
- REV3L | c.6752_6753+4del p.X2251_splice | Splice Site (DEL) | VAF 12/47 reads (26%) | called by mutect2, pindel, varscan2
- RGS2 | c.13_14dup p.M5Ifs*30 | Frame Shift Ins (INS) | VAF 12/49 reads (24%) | called by mutect2, pindel, varscan2
- RIOK3 | c.444_445insGGTTGGTT p.P149Gfs*24 | Frame Shift Ins (INS) | VAF 18/63 reads (29%) | called by mutect2, pindel
- RLF | c.5401_5404del p.S1801Hfs*7 | Frame Shift Del (DEL) | VAF 17/80 reads (21%) | called by mutect2, pindel, varscan2
- RPP25L | c.201_204dup p.S69Cfs*5 | Frame Shift Ins (INS) | VAF 4/26 reads (15%) | called by mutect2, pindel
- SCN3A | c.495_496dup p.T166Ifs*7 | Frame Shift Ins (INS) | VAF 9/45 reads (20%) | called by mutect2, pindel, varscan2
- SEC23B | c.1564_1576del p.E522Cfs*2 | Frame Shift Del (DEL) | VAF 21/105 reads (20%) | called by mutect2, pindel, varscan2
- SETBP1 | c.500_503dup p.D168Efs*2 | Frame Shift Ins (INS) | VAF 16/138 reads (12%) | called by mutect2, pindel
- SH2D4A | c.1142_1143dup p.A382Mfs*112 | Frame Shift Ins (INS) | VAF 18/68 reads (26%) | called by mutect2, pindel, varscan2
- SLC2A6 | c.1443_1445dup p.C482dup | In Frame Ins (INS) | VAF 14/46 reads (30%) | called by mutect2, varscan2
- SLC30A7 | c.162_163del p.Y55Rfs*20 | Frame Shift Del (DEL) | VAF 10/48 reads (21%) | called by pindel, varscan2
- SOCS7 | c.1518del p.I507Sfs*30 | Frame Shift Del (DEL) | VAF 9/92 reads (10%) | called by mutect2, pindel, varscan2
- SP100 | c.312_313dup p.V105Efs*34 | Frame Shift Ins (INS) | VAF 32/115 reads (28%) | called by mutect2, pindel, varscan2
- SRCIN1 | c.921_924del p.N308Gfs*100 (on ENST00000621492; = p.N274Gfs*100 on NM_025248.3) | Frame Shift Del (DEL) | VAF 7/45 reads (16%) | called by mutect2, pindel, varscan2
- SSBP1 | c.24+4_24+7dup | Splice Region (INS) | VAF 16/117 reads (14%) | called by mutect2, pindel, varscan2
- STKLD1 | c.1852_1854dup p.L618dup | In Frame Ins (INS) | VAF 19/77 reads (25%) | called by mutect2, varscan2
- STX1A | c.293_296dup p.I100Vfs*14 | Frame Shift Ins (INS) | VAF 14/46 reads (30%) | called by pindel, varscan2
- TAPBP | c.5_7del p.K2_S3delinsT | In Frame Del (DEL) | VAF 7/53 reads (13%) | called by mutect2, pindel, varscan2
- TGIF1 | c.446_454del p.R149_V152delinsL (on ENST00000330513 / NM_001374396.1; = p.R169_V172delinsL on NM_003244.4) | In Frame Del (DEL) | VAF 9/51 reads (18%) | called by mutect2, pindel, varscan2
- TGM7 | c.115dup p.Q39Pfs*25 | Frame Shift Ins (INS) | VAF 20/110 reads (18%) | called by mutect2, pindel, varscan2
- TNFRSF8 | c.221_227delinsG p.Y74_D76delinsC | In Frame Del (DEL) | VAF 10/36 reads (28%) | called by pindel, varscan2*
- TP53 | c.715_716del p.N239Qfs*24 | Frame Shift Del (DEL) | VAF 9/39 reads (23%) | called by mutect2, pindel, varscan2
- TP53BP1 | c.330_333dup p.P112Vfs*51 | Frame Shift Ins (INS) | VAF 31/133 reads (23%) | called by mutect2, pindel, varscan2
- TRIM40 | c.689_689+3del p.X230_splice (on ENST00000376724; = p.X201_splice on NM_138700.4) | Splice Site (DEL) | VAF 16/63 reads (25%) | called by mutect2, pindel, varscan2
- TRIM74 | c.752_*6del | Nonstop Mutation (DEL) | VAF 8/62 reads (13%) | called by mutect2, pindel
- TUBGCP6 | c.17_20dup p.F8Afs*7 | Frame Shift Ins (INS) | VAF 6/16 reads (38%) | called by mutect2, varscan2
- UBE2Z | c.360_363dup p.V122Rfs*4 | Frame Shift Ins (INS) | VAF 40/182 reads (22%) | called by mutect2, varscan2
- UNC79 | c.6501_6503dup p.S2168dup (on ENST00000393151 / NM_001346218.2; = p.S1991dup on NM_020818.5) | In Frame Ins (INS) | VAF 49/177 reads (28%) | called by mutect2, pindel, varscan2
- URM1 | c.236_237dup p.G80Wfs*85 | Frame Shift Ins (INS) | VAF 9/40 reads (23%) | called by mutect2, pindel, varscan2
- VEZF1 | c.648_651del p.M217Lfs*4 | Frame Shift Del (DEL) | VAF 8/59 reads (14%) | called by mutect2, pindel, varscan2
- VSIG1 | c.624_626dup p.Y209dup | In Frame Ins (INS) | VAF 88/406 reads (22%) | called by mutect2, pindel, varscan2
- ZBTB24 | c.231_240del p.Y77* | Frame Shift Del (DEL) | VAF 36/144 reads (25%) | called by mutect2, pindel, varscan2
- ZFP14 | c.536_538dup p.K179dup | In Frame Ins (INS) | VAF 23/158 reads (15%) | called by mutect2, pindel, varscan2
- ZMYND12 | c.463dup p.Q155Pfs*11 | Frame Shift Ins (INS) | VAF 10/93 reads (11%) | called by mutect2, pindel, varscan2
- ZNF248 | c.816_818dup p.S273dup | In Frame Ins (INS) | VAF 21/108 reads (19%) | called by mutect2, pindel, varscan2
- ABCC9 | c.3615C>T p.N1205= | Silent (SNP) | VAF 21/130 reads (16%) | catalogued as rs17846779, COSV53967090, COSV99685956; called by muse, mutect2, varscan2
- DDX56 | c.207G>A p.L69= | Silent (SNP) | VAF 27/93 reads (29%) | catalogued as rs769845263, COSV99215560; called by muse, mutect2, varscan2
- ESRRB | c.69G>A p.P23= | Silent (SNP) | VAF 18/54 reads (33%) | catalogued as rs1064436, COSV55060054; called by muse, mutect2, varscan2
- GSPT2 | c.1098T>C p.C366= | Silent (SNP) | VAF 17/58 reads (29%) | catalogued as COSV100468215; called by muse, mutect2, varscan2
- NLRC5 | c.840G>T p.L280= | Silent (SNP) | VAF 11/85 reads (13%) | catalogued as COSV99347547; called by muse, mutect2, varscan2
- NOD2 | c.807G>A p.P269= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as rs369766454; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- OR10A2 | c.198C>A p.P66= | Silent (SNP) | VAF 38/130 reads (29%) | catalogued as COSV100225070; called by muse, varscan2
- OR8B2 | c.72G>A p.R24= | Silent (SNP) | VAF 68/277 reads (25%) | catalogued as COSV100899496, COSV66665742; called by muse, mutect2, varscan2
- PCDHA12 | c.1746G>A p.P582= | Silent (SNP) | VAF 35/126 reads (28%) | catalogued as COSV56530033; called by muse, mutect2, varscan2
- PCSK1 | c.1083C>T p.T361= | Silent (SNP) | VAF 17/88 reads (19%) | catalogued as rs1288453060, COSV60737386; called by muse, mutect2, varscan2
- RNF111 | c.1083G>A p.E361= | Silent (SNP) | VAF 10/56 reads (18%) | catalogued as COSV100789091; called by muse, mutect2, varscan2
- RPL24 | c.141G>C p.R47= | Silent (SNP) | VAF 33/158 reads (21%) | catalogued as COSV101231187; called by muse, mutect2, varscan2
- SEC16A | c.3777T>C p.Y1259= | Silent (SNP) | VAF 20/75 reads (27%) | catalogued as COSV99258866; called by muse, mutect2, varscan2
- SZT2 | c.10230C>G p.V3410= (on ENST00000634258 / NM_001365999.1; = p.V3353= on NM_015284.4) | Silent (SNP) | VAF 10/63 reads (16%) | catalogued as COSV100981302; called by muse, mutect2, varscan2
- VCX3B | c.66C>A p.S22= | Silent (SNP) | VAF 19/127 reads (15%) | catalogued as COSV101123800; called by muse, mutect2, varscan2
- YBX3 | c.408A>G p.G136= | Silent (SNP) | VAF 21/75 reads (28%) | catalogued as rs1401331837, COSV99685189; called by muse, mutect2, varscan2
- AC092718.9 | chr16:81149726 del C | 5'Flank (DEL) | VAF 6/20 reads (30%) | catalogued as rs749750563; called by mutect2, pindel, varscan2
- AL645933.1 | chr6:31463925 ins TAT | 5'Flank (INS) | VAF 12/72 reads (17%) | called by mutect2, pindel, varscan2
- AP000769.3 | chr11:65505826 ins ACAT | 5'Flank (INS) | VAF 16/72 reads (22%) | called by mutect2, pindel, varscan2
- FGF8 | c.157-30del | Intron (DEL) | VAF 11/47 reads (23%) | called by mutect2, pindel, varscan2
- RPL27A | c.143+206dup | Intron (INS) | VAF 33/160 reads (21%) | called by mutect2, pindel, varscan2
